Gene-level copy-number profile of tumor specimen C3N-04695-03 from CPTAC case C3N-04695, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.0 years (24,823 days).
Specimen C3N-04695-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7da13427-d0d2-4b7f-93f6-7e9c8be8a29a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04695-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/f7b55f58-6358-4928-b793-c1406dd1bd21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 6,531; copy number 2: 48,862; copy number 3: 440; copy number 4: 2,851; copy number 5: 74; copy number 41: 35; copy number 56: 2; copy number 60: 5; copy number 95: 1.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–23,438,700, 77 genes (broad region; genes not listed).
- chr9:24,905,469–25,938,434, 5 genes: RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1.
- chr9:26,642,697–27,944,497, 26 genes: AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr9:28,863,626–29,826,711, 6 genes: MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 117 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,795,623–203,854,999, 3 genes, copy number 41 (within-gene range 2–41): ZC3H11A, ZBED6, AC114402.2.
- chr1:203,835,585–204,728,106, 32 genes, copy number 41: RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr7:54,752,250–55,260,256, 8 genes, copy number 56–95: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:100,200,653–100,272,218, 1 gene, copy number 5 (within-gene range 4–5): CASTOR3.
- chr7:100,307,702–100,867,010, 40 genes, copy number 5: SPDYE3, PMS2P1, Y_RNA, STAG3L5P, STAG3L5P-PVRIG2P-PILRB, PILRB, PVRIG2P, MIR6840, PILRA, AC005071.1, ZCWPW1, MEPCE, AC092849.1, PPP1R35, PPP1R35-AS1, C7orf61, TSC22D4, NYAP1, AC069281.1, RN7SL416P, AGFG2, IRS3P, SAP25, AC069281.2, LRCH4, FBXO24, PCOLCE-AS1, PCOLCE, MOSPD3, TFR2, ACTL6B, GNB2, GIGYF1, POP7, EPO, ZAN, EPHB4, RN7SL750P, SLC12A9, SLC12A9-AS1.
- chr7:149,321,865–150,412,470, 33 genes, copy number 5: AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1, ZNF467, SSPOP, ZNF862, AC004877.2, AC004877.1, ATP6V0E2-AS1, ATP6V0E2, AC093458.1, AC093458.2, AC092681.3, AC092681.1, AC092681.2, AC092666.1, AC092666.2, ACTR3C, ZBED6CL, LRRC61, AC005586.1, RARRES2, REPIN1-AS1, REPIN1, ZNF775, AC073111.2, ZNF775-AS1, AC073111.3.

Autosomal genes at a single copy (total copy number 1): 3,675. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
